Somatic mutation profile of tumor specimen TCGA-W6-AA0S-01A (aliquot TCGA-W6-AA0S-01A-11D-A417-09) from TCGA case TCGA-W6-AA0S, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 46.4 years (16,951 days).
Specimen TCGA-W6-AA0S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e36402bb-f452-4847-9b90-47c3fdbf17a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W6-AA0S-10A (Blood Derived Normal), aliquot TCGA-W6-AA0S-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86e15bb0-bdca-484e-97de-d8a0340d277b

The open-access MAF lists 37 somatic variants for this specimen: 31 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 24, Silent 6, Frame Shift Ins 3, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- CCNB3 | c.3535C>T p.H1179Y | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52080987; called by muse, mutect2, varscan2
- CD177 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 49/73 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs748857323; called by muse, mutect2, varscan2
- CLCN5 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as rs1557193914; called by muse, mutect2, varscan2
- JAKMIP2 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV54597684, COSV99507827; called by muse, mutect2, varscan2
- LCE2B | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.958); catalogued as rs779881467, COSV64227620; called by muse, mutect2, varscan2
- LRP1B | c.3646G>C p.D1216H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as COSV67230462; called by muse, mutect2, varscan2
- MTERF2 | c.1073_1074del p.E358Vfs*2 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | catalogued as rs774235907; called by pindel, varscan2
- MTFMT | c.703A>G p.M235V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs746080337; called by muse, mutect2, varscan2
- NF2 | c.999+2T>G p.X333_splice | Splice Site (SNP) | VAF 6/23 reads (26%) | catalogued as COSV58530171; called by muse, mutect2, varscan2
- PCDHGA9 | c.1139G>C p.G380A | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.818); catalogued as COSV99535537; called by muse, mutect2, varscan2
- PIH1D2 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54775348; called by muse, mutect2, varscan2
- PTCH1 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs767601899; ClinVar: uncertain significance; called by muse, varscan2
- SOX5 | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.904); catalogued as rs751975537, COSV58638990; called by muse, mutect2, varscan2
- TAS2R3 | c.84G>T p.E28D | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs1255665686; called by muse, mutect2
- TMEM198 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs199837128; called by muse, varscan2
- TRAF4 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52047532; called by muse, mutect2, varscan2
- WFIKKN2 | c.79G>T p.G27W | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV60960254; called by muse, mutect2, varscan2
- BCO2 | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- BRD2 | c.1412dup p.G472Wfs*12 | Frame Shift Ins (INS) | VAF 11/20 reads (55%) | called by mutect2, pindel, varscan2
- HSPA13 | c.1402dup p.T468Nfs*18 | Frame Shift Ins (INS) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- ITPR2 | c.3467C>G p.S1156* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- LAMA4 | c.4208C>A p.P1403H (on ENST00000230538 / NM_001105206.3; = p.P1396H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LEO1 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP1A | c.4975G>A p.E1659K | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MPDZ | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRAMEF12 | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRMT3 | c.1011T>G p.F337L | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2
- SP140L | c.1037dup p.Y347Lfs*29 | Frame Shift Ins (INS) | VAF 38/96 reads (40%) | called by mutect2, varscan2
- SRCAP | c.8583del p.R2862Gfs*24 | Frame Shift Del (DEL) | VAF 19/65 reads (29%) | called by mutect2, pindel, varscan2
- USP47 | c.3156G>C p.L1052F (on ENST00000399455 / NM_001372095.1; = p.L964F on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CEP68 | c.2160C>T p.H720= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs777921262, COSV53127955; called by muse, mutect2, varscan2
- JAKMIP2 | c.744C>G p.L248= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as rs773994760; called by muse, mutect2, varscan2
- LRRC55 | c.243G>A p.P81= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs762291521; called by muse, mutect2, varscan2
- NLGN1 | c.2463C>A p.T821= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as rs745994171; called by muse, mutect2, varscan2
- YAP1 | c.1422G>T p.L474= (on ENST00000282441 / NM_001130145.3; = p.L420= on NM_006106.5) | Silent (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- ZBBX | c.1659C>A p.S553= | Silent (SNP) | VAF 46/104 reads (44%) | called by muse, mutect2, varscan2
